Somatic mutation profile of tumor specimen C3L-01328-01 (aliquot CPT0083270006_1) from CPTAC case C3L-01328, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,268 days).
Specimen C3L-01328-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae371844-26ac-4109-9b03-704ce09e39c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01328-31 (Blood Derived Normal), aliquot CPT0081770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab714ad8-a0bb-419e-a06c-e38f0b445ea7

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 256/1003 reads (26%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 376/954 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 211/661 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- CCT8L2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 113/856 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs147789853, CM142324; called by muse, mutect2, varscan2
- CEMIP | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 100/1012 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs562341405; called by muse, mutect2
- FGF6 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 274/580 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs767850309, COSV57404471; called by muse, mutect2, varscan2
- FOXI3 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 220/1027 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs922394321; called by muse, mutect2, varscan2
- HMCN1 | c.16658G>A p.R5553Q | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148530862; called by muse, mutect2, varscan2
- LY9 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 34/503 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs369975202; called by muse, mutect2
- NALCN | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs764045715, COSV51954405, COSV99215015; called by muse, varscan2
- NCKIPSD | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 142/541 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs201067488, COSV99583932; called by muse, mutect2, varscan2
- NEK1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71457147; called by muse, mutect2, varscan2
- PA2G4 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 17/545 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV57567788; called by muse, mutect2
- ARID1A | c.2549dup p.Y850* | Nonsense Mutation (INS) | VAF 98/584 reads (17%) | called by mutect2, pindel, varscan2
- C12orf43 | c.186C>G p.L62= | Splice Region (SNP) | VAF 128/691 reads (19%) | called by muse, mutect2, varscan2
- CREG2 | c.567del p.M190Wfs*4 | Frame Shift Del (DEL) | VAF 62/680 reads (9%) | called by mutect2, pindel
- MLNR | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 70/704 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PAPPA2 | c.3898T>C p.Y1300H | Missense Mutation (SNP) | VAF 79/535 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBR1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 112/542 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNIP | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 111/1337 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WASF3 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 89/787 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ARRDC2 | c.255C>T p.R85= | Silent (SNP) | VAF 97/439 reads (22%) | catalogued as rs779259957; called by muse, mutect2, varscan2
- CLSTN1 | c.471G>T p.V157= (on ENST00000377298 / NM_001009566.3; = p.V147= on NM_014944.4) | Silent (SNP) | VAF 77/660 reads (12%) | called by muse, mutect2, varscan2
- GPAT3 | c.558C>T p.L186= | Silent (SNP) | VAF 83/449 reads (18%) | called by muse, mutect2, varscan2
- NPAS4 | c.360C>T p.Y120= | Silent (SNP) | VAF 74/774 reads (10%) | catalogued as rs377576767, COSV60650442; called by muse, mutect2
- OR10H5 | c.99G>C p.L33= | Silent (SNP) | VAF 44/480 reads (9%) | catalogued as COSV100454611; called by muse, mutect2
- PRDM14 | c.300G>A p.P100= | Silent (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1041G>A p.L347= | Silent (SNP) | VAF 94/389 reads (24%) | called by muse, mutect2, varscan2
- SYCP3 | c.45G>A p.P15= | Silent (SNP) | VAF 175/787 reads (22%) | catalogued as rs566435135; called by muse, mutect2, varscan2
- BTBD11 | c.2991+20G>A | Intron (SNP) | VAF 44/337 reads (13%) | called by muse, mutect2, varscan2
- FOXO1 | c.631-50248A>G | Intron (SNP) | VAF 21/212 reads (10%) | catalogued as rs879549555; called by muse, mutect2
- IGFN1 | c.1242-673G>A | Intron (SNP) | VAF 64/354 reads (18%) | catalogued as rs1415207837; called by muse, mutect2, varscan2
- SLC6A19 | c.-51C>T | 5'UTR (SNP) | VAF 141/597 reads (24%) | catalogued as rs745636396; called by muse, mutect2, varscan2
